CCDI case PBBYTD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a5a74ae4-599c-4481-a7cf-353ad0fd9716

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 17.1 years (6,241 days).

Biospecimens (3 samples)
- Sample 0DL0IT: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL0J2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DL0JC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
